Gene-level copy-number profile of specimen HCM-BROD-0685-C71-85A from HCMI case HCM-BROD-0685-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.8 years (25,506 days).
Specimen HCM-BROD-0685-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebfd1e26-f70c-48b6-9f5e-060864152050.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0685-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/f090f265-e02c-476d-b859-f7f23113a600

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 309; copy number 1: 21,821; copy number 2: 35,682; copy number 3: 1,044; copy number 20: 8; copy number 21: 15; copy number 22: 2; copy number 23: 27; copy number 24: 7.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,877,721–47,246,601, 8 genes (within-gene range 0–1): PTH1R, AC109583.3, CCDC12, NBEAL2, NRADDP, SETD2, MRPL57P3, KIF9-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 59 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:14,503,661–14,624,191, 4 genes, copy number 23 (within-gene range 2–23): PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1.
- chr12:23,108,458–23,251,499, 3 genes, copy number 24 (within-gene range 1–24): AC087258.1, AC087235.2, AC087235.1.
- chr12:28,133,249–28,581,511, 1 gene, copy number 23 (within-gene range 1–23): CCDC91.
- chr12:28,236,227–28,319,463, 2 genes, copy number 23: AC022079.1, RNU4-54P.
- chr12:37,575,587–37,576,384, 1 gene, copy number 20: ZNF970P.
- chr12:60,092,864–60,096,071, 1 gene, copy number 23: AC080011.1.
- chr12:65,017,468–65,966,291, 19 genes, copy number 23: AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:81,257,975–81,759,553, 4 genes, copy number 24 (within-gene range 1–24): PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr12:97,995,383–98,292,445, 2 genes, copy number 22: MIR4303, AC016152.1.
- chr12:110,372,900–110,583,318, 12 genes, copy number 21: ANAPC7, AC144548.1, HMGA1P3, ARPC3, GPN3, RPL31P49, FAM216A, VPS29, AC002350.1, AC002350.2, RAD9B, PPTC7.
- chr12:110,831,779–111,350,554, 7 genes, copy number 20 (within-gene range 1–20): AC002375.1, RPL29P25, CCDC63, MYL2, LINC01405, AC002351.1, CUX2.
- chr12:118,981,541–119,163,051, 2 genes, copy number 21 (within-gene range 1–21): SRRM4, AC087885.1.
- chr12:119,031,039–119,116,961, 1 gene, copy number 21: AC084361.1.

Autosomal genes at a single copy (total copy number 1): 19,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
